Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAI8, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAI8-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; seminoma; diameter 2.0 cm; tumor confined to testis in available slides; no angio-invasion; no invasion in rete testis.

Date of procurement (= date of orchidectomy):

ICD O-3
Seminoma NOS 9061/3
Site: O Testis NOS C62.9
JAD 3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 6ef0787d-1c13-4d46-8dfa-d141f11520da (TCGA-2G-AAI8-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).